Gene-level copy-number profile of tumor specimen TCGA-DD-AADY-01A from TCGA case TCGA-DD-AADY, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 55.4 years (20,233 days).
Specimen TCGA-DD-AADY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.c335f228-c422-4237-ab2b-995b4fd0bbc4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AADY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fdffe01e-9c6d-4943-96e2-8f5e0c36e796

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 16,180; copy number 2: 40,731; copy number 3: 71; copy number 4: 1,307; copy number 5: 1,531.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AADY-01A-11D-A40Q-01): tumor purity 0.92, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,531 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–199,909,648, 1,467 genes, copy number 5 (broad region; genes not listed).
- chr11:69,294,151–70,436,584, 36 genes, copy number 5: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,647,562, 4 genes, copy number 5: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2.
- chr11:74,748,849–75,351,705, 24 genes, copy number 5 (within-gene range 3–5): RNF169, XRRA1, AP000560.1, RN7SL239P, AP001992.1, AP001992.2, SPCS2, RNU6-216P, NEU3, AP003175.1, OR2AT2P, NPM1P50, OR2AT4, AP001972.4, SLCO2B1, OR2AT1P, AP001972.3, ZDHHC20P3, TPBGL, ARRB1, AP001972.1, AP001972.5, AP001972.2, MIR326.

Autosomal genes at a single copy (total copy number 1): 16,180. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
